Somatic mutation profile of tumor specimen TARGET-10-PASGFH-09A (aliquot TARGET-10-PASGFH-09A-01D) from TARGET case TARGET-10-PASGFH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.8 years (6,488 days).
Specimen TARGET-10-PASGFH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cbda0dc-8a70-44b0-a6a1-1cf1011fd31c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASGFH-10A (Blood Derived Normal), aliquot TARGET-10-PASGFH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec7c5336-720e-4147-a385-45edfa2f91a7

The open-access MAF lists 42 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, Nonsense Mutation 5, Intron 5, RNA 1, Splice Site 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.9901C>T p.P3301S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.777); catalogued as COSV71291305; called by muse, mutect2, varscan2
- ADGRF1 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs773948526, COSV51945392; called by muse, mutect2, varscan2
- BRAT1 | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765404910, COSV61396311; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C11orf53 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT tolerated (0.19); PolyPhen benign (0.068); catalogued as rs372697986; called by muse, mutect2, varscan2
- CTPS1 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as rs752105512, COSV65453255; called by muse, mutect2, varscan2
- DIP2C | c.4408G>A p.V1470I | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781358014, COSV55167546; called by muse, mutect2, varscan2
- DMGDH | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs113405129; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGF1 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as rs774480739, COSV61804125; called by muse, mutect2, varscan2
- GCN1 | c.5828C>T p.T1943M | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs749551221, COSV56111036; called by muse, mutect2, varscan2
- GRK3 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV60798310; called by muse, mutect2, varscan2
- GRK6 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs777094286, COSV62683395; called by muse, mutect2, varscan2
- IKZF1 | c.40+1G>C p.X14_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | catalogued as COSV58783219, COSV58789121; called by muse, mutect2, varscan2
- JAK3 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752661478, COSV71685384, COSV71685422, COSV71685783; called by muse, mutect2, varscan2
- KIF16B | c.2164G>T p.E722* | Nonsense Mutation (SNP) | VAF 47/120 reads (39%) | catalogued as COSV61709689; called by muse, mutect2, varscan2
- KRT38 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 35/85 reads (41%) | catalogued as COSV55846765; called by muse, mutect2, varscan2
- MC4R | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs13447332, CM121075, CM990834, COSV55352467; called by muse, mutect2, varscan2
- MUC16 | c.20466G>C p.K6822N | Missense Mutation (SNP) | VAF 49/58 reads (84%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.041); catalogued as COSV67479316; called by muse, mutect2, varscan2
- NBEA | c.7996C>T p.R2666W | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs371745545, COSV59766705; called by muse, mutect2, varscan2
- NEUROD2 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56911427; called by muse, mutect2, varscan2
- NOTCH1 | c.7309G>T p.E2437* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV53071303; called by muse, mutect2, varscan2
- NTNG2 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.987); catalogued as rs755237562, COSV62367827; called by muse, mutect2, varscan2
- NXNL1 | c.244T>G p.S82A | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV57324991; called by muse, mutect2, varscan2
- PPL | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs140336107; called by muse, mutect2, varscan2
- STAT5B | c.1254T>A p.N418K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV53184411; called by muse, mutect2, varscan2
- STEAP2 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 43/111 reads (39%) | catalogued as rs759069761, COSV55291911; called by muse, mutect2, varscan2
- STXBP5L | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 19/38 reads (50%) | catalogued as rs1388311069, COSV56523458; called by muse, mutect2, varscan2
- SUPT5H | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.18); catalogued as rs757236653, COSV63240896; called by muse, mutect2, varscan2
- KDM6A | c.3872dup p.M1291Ifs*3 | Frame Shift Ins (INS) | VAF 14/24 reads (58%) | called by mutect2, pindel, varscan2
- C11orf24 | c.588A>G p.P196= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- FGD6 | c.4164A>G p.K1388= | Silent (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- PRDM8 | c.2058C>T p.T686= | Silent (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- PRR23A | c.648C>T p.F216= | Silent (SNP) | VAF 19/24 reads (79%) | catalogued as rs748247710, COSV67213461; called by muse, mutect2, varscan2
- RIPK2 | c.1086G>A p.R362= | Silent (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- RTL1 | c.792C>T p.I264= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs964491217, COSV66016464; called by muse, mutect2, varscan2
- DPP6 | c.2451+46C>A | Intron (SNP) | VAF 25/36 reads (69%) | called by muse, mutect2, varscan2
- KCTD15 | c.693+46G>A | Intron (SNP) | VAF 12/34 reads (35%) | catalogued as rs1043790116, COSV99393378; called by muse, mutect2, varscan2
- MIF | c.108+46G>A | Intron (SNP) | VAF 5/8 reads (63%) | called by muse, mutect2, varscan2
- RUNX2 | c.59-31C>T | Intron (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- TPH2 | c.-53T>A | 5'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- TUBB7P | n.1037C>A | RNA (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- ZSWIM9 | c.588+3864C>T | Intron (SNP) | VAF 8/18 reads (44%) | catalogued as rs1440968365; called by muse, mutect2
